Somatic mutation profile of tumor specimen TCGA-2G-AAGV-01A (aliquot TCGA-2G-AAGV-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAGV, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Teratoma, benign; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 23.6 years (8,612 days).
Specimen TCGA-2G-AAGV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 948f847d-ee7a-4c1e-8c6e-7c19e03bfa9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAGV-10A (Blood Derived Normal), aliquot TCGA-2G-AAGV-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c88a3da-aa60-4715-8429-102c49807841

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LY6K | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.549); catalogued as rs782760195; called by muse, mutect2
- PGAP6 | c.1999G>A p.V667M | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.305); catalogued as rs780011039, COSV51738557; called by muse, mutect2, varscan2
- CPSF1 | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMPD4 | c.2338C>T p.L780F (on ENST00000409031 / NM_017951.4; = p.L751F on NM_017751.4) | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYNJ2 | c.4303G>A p.D1435N | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZZEF1 | c.6496C>A p.L2166M | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2
- CSMD1 | c.3258C>T p.C1086= (on ENST00000520002; = p.C1085= on NM_033225.6) | Silent (SNP) | VAF 28/97 reads (29%) | called by muse, mutect2, varscan2
